Somatic mutation profile of tumor specimen 0DOLV5 from CCDI case PBCCRF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 19.7 years (7,199 days).
Specimen 0DOLV5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e10ff3d-31c0-4b94-821a-20350c5896eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOLUT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b60dae0-fe86-40a4-84d7-22e865107f67

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1966A>G p.K656E (on ENST00000447712 / NM_023110.3; = p.K654E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 251/1044 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869320694, COSV58327161, COSV58340654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FGFR1 | c.1681G>A p.V561M (on ENST00000447712 / NM_023110.3; = p.V559M on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/658 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58333193; called by muse, mutect2, varscan2
- SFMBT2 | c.2222G>A p.R741Q | Missense Mutation (SNP) | VAF 165/691 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs199600207, COSV100739559, COSV62812569; called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 48/1290 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- SLC34A1 | c.1525G>T p.A509S | Missense Mutation (SNP) | VAF 126/537 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SMIM10L2B | c.-73G>T | 5'UTR (SNP) | VAF 5/39 reads (13%) | called by muse, varscan2
- ZC3H3 | c.*94C>G | 3'UTR (SNP) | VAF 52/150 reads (35%) | called by muse, mutect2, varscan2
